TCGA case TCGA-02-0107 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/372a4cc6-8fc9-4157-9cdc-fe020b176249

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 537 days (1.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 56.3 years (20,557 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 103 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 100 days; Days to treatment end: 130 days; Number of cycles: 1; Treatment dose: 200 mg/m2; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 56.7 years (20,703 days); Days to diagnosis: 146 days; Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 146 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 146 days.
- Days to follow up: 537 days (1.5 years); Disease response: With Tumor.
- Karnofsky performance status: 80.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.1.
  Slide TCGA-02-0107-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-02-0107-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-02-0107-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Treated primary GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: Yes; Method initial path diagnosis: Tumor resection.
- Drug treatment, Route of administrations: Route of administration: PO.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Per enrollment form, patient received neo-adjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 537 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 537 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 146 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0107-01): tumor purity 0.18, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).
